Surgical pathology report (de-identified scan), TCGA case TCGA-77-8153, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8153-01A (Primary Tumor).

[page 1 of 2]
HISTORY

No clinical notes.

MACROSCOPIC

One specimen received.

The specimen is labelled 'right lower lobe' and consists of a right lower lobectomy with a inflated measurements of 115 superior to inferior x 120 mm anterior to posterior x 70 mm medial to lateral. Sectioning reveals a firm pale lobulated mass measuring 48 x 48 x 45 mm. The mass is 15 mm from the bronchial resection margin, and 10 mm from the hilar resection margin. The mass is 3 mm clear of the stapled resection margin, focally abuts the pleural surface. The non-neoplastic lung parenchyma appears normal. [1A, 2 shaves of bronchial resection margin; 1B-C, hilar lymph nodes; 1D, TS hilar resection margin; 1E, tumour and pleura; 1F, tumour and pleura; 1G, tumour and pleura; 1H, subpleural lymph nodes; 1I, subpleural nodes; 1J, non-neoplastic lung tissue; 1K bronchial resection margin sampled at time of tumour bank sampling; 1L pulmonary artery resection margin].

MICROSCOPIC

Sections show a partially necrotic poorly differentiated squamous cell carcinoma. The lesion is subpleural and approaches central bronchi. There is possible involvement of the visceral pleura in the region of the interlobar fissure but tumour does not extend into the overlying adherent lung. Special stains will be performed to assess pleural involvement. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. The adjacent lung shows minor evidence of emphysema and there is a small amount of peribronchial carbon dust deposition. An area of subpleural haemorrhage is noted but no subpleural lymph nodes are identified.

SUMMARY

Right lower lobe:

- A: Poorly differentiated squamous cell carcinoma; 48 mm in maximal dimension.
- B: No blood vessel, lymphatic or perineural invasion present.
- C: Possible visceral pleural invasion identified; clear of bronchial margin.
- D: No lymph node metastases.
- E: T2N0
- F: Non-neoplastic lung: No significant changes.

[page 2 of 2]
Histopathology Report

SUPPLEMENTARY REPORT

Special stains confirm the presence of invasion into but not through the visceral pleura.

SUMMARY

Right lower lobe:

A: Poorly differentiated squamous cell carcinoma; 48 mm in maximal dimension.

B: No blood vessel, lymphatic or perineural invasion present.

C: Visceral pleural invasion identified; clear of bronchial margin.

D: No lymph node metastases.

E: T2N0

F: Non-neoplastic lung: No significant changes.

c.c. Lung Cancer Registry

Source: NCI Genomic Data Commons file efc2ca19-5499-4fcf-b57d-44fb651059fc (TCGA-77-8153.310BE22D-8980-4D51-83A9-DFC620B73F5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).